Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7231, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7231-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY:

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO: [REDACTED]

Pre-Op Diagnosis

Prostate cancer

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled "[REDACTED] - prostate"
Is a 53 gram previously inked partially sectioned markedly distorted prostate gland with attached bilateral seminal vesicles. The prostate gland on reconstruction is approximately 5.0 x 4.4 x 3.9 cm and has a shaggy capsule. The urethra appears patent. The specimen is step sectioned to reveal a bulging tan gray multinodular fibrotic cut surface with compression of the urethra by the lateral lobes. Noted in the left posterior aspect extending to within 0.3 cm of the apex there is a poorly defined approximately 2.2 x 1.6 x 1.0 cm area of pale tan gray to yellow slightly indurated fibrosis which focally extends into the left lateral lobe and right posterior lobe. This grossly focally extends to within 0.1 cm of the inked nearest margin. This extends toward the mid region of the specimen. The seminal vesicles together measure 5.0 x 2.0 x 0.9 cm. These have lobulated outer surfaces with multicystic gray tan fibrotic cut surfaces. Also received in the same container are three tissue cassettes each labeled "[REDACTED]". Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical (proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe

[page 2 of 2]
proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

Microscopic Description:
Slides reviewed.

Final Diagnosis

Radical prostatectomy:

Carcinoma.

Tumor characteristics:

Histologic type: Adenocarcinoma, conventional type.

Prostate size: 53 grams, 5.0 x 4.4 x 3.9 cm.

Tumor quantitation: Approximately 10% of gland volume.

Gleason grade:

Primary pattern: 3/5

Secondary pattern: 4/5

Total score: 7/10

Extra prostatic extension: Not identified.

Seminal vesicle involvement: Not identified.

Lymphovascular space invasion: Not identified.

High grade PIN: Present.

Treatment affect: Not identified.

Surgical margin status: Margins uninvolved.

Lymph node status:

Total number of lymph nodes received: None.

Other significant findings:

None

pTN stage: pT2c, NX PAS 9 SPC-A

CPT: 88309

Comments

This report has been finalized at the [REDACTED] Campus.

[REDACTED]

Source: NCI Genomic Data Commons file 5563c974-1d3f-4843-a139-c2fceae360f7 (TCGA-HC-7231.4A904B18-B8CF-4666-A384-2B3CE33F7891.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).